Surgical pathology report (de-identified scan), TCGA case TCGA-IN-7808, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-IN-7808-01A (Primary Tumor).

ADDENDA:**Addendum**

HER2 FISH STUDIES PERFORMED ON THE ADENOCARCINOMA ARE NEGATIVE

Cells Analyzed: 74

% Hyperdiploid: 9(12.2%)

HER2 IMMUNOPEROXIDASE STUDIES PERFORMED ON THE ADENOCARCINOMA ARE NEGATIVE.

IHC score: 0.

This result should be integrated with all clinical and pathologic data in the determination of a comprehensive diagnostic and treatment plan.

FINAL DIAGNOSIS:

PART 1: SKIN, LEFT CHEST WALL, EXCISION –
ANGIOMA.

PART 2: LYMPH NODE, LEVEL 8, EXCISION –
THREE (3) LYMPH NODES, NEGATIVE FOR METASTATIC CARCINOMA.

PART 3: LYMPH NODE, GASTRIC, EXCISION –
METASTATIC SIGNET RING CELL CARCINOMA TO ONE (1) LYMPH NODE.

PART 4: LIVER, WEDGE RESECTION –
A. CAUTERIZED LIVER WITH FOCAL CHRONIC INFLAMMATION.
B. NEGATIVE FOR MALIGNANCY.

PART 5: LYMPH NODES, ILIAC, EXCISION –
METASTATIC SIGNET RING CELL CARCINOMA TO THREE (3) LYMPH NODES.

PART 6: LYMPH NODE, GASTRIC, EXCISION –
METASTATIC SIGNET RING CELL CARCINOMA TO ONE (1) LYMPH NODE.

PART 7: ESOPHAGUS AND STOMACH, ESOPHAGOGASTRECTOMY –
A. POORLY DIFFERENTIATED INVASIVE SIGNET RING CELL ADENOCARCINOMA WITH FOCAL MUCINOUS FEATURES, ARISING AT THE GASTROESOPHAGEAL JUNCTION.
B. CARCINOMA MEASURES GROSSLY 3.5 X 3.0 CM (SEE COMMENT) AND INVADES THROUGH ESOPHAGEAL ADVENTITIA AND GASTRIC SEROSA.
C. EXTENSIVE LYMPH VASCULAR AND PERINEURAL SPACE INVASION IDENTIFIED.
D. METASTATIC CARCINOMA TO SIXTEEN OF SIXTEEN LYMPH NODES WITH EXTENSIVE EXTRACAPSULAR SPACE EXTENSION (16/16).
E. CARCINOMA EXTENDS TO BOTH PROXIMAL AND DISTAL MARGINS (SEE PART 8 FOR FINAL MUCOSAL MARGINS).
F. CARCINOMA INVOLVES SEROSAL/ADVENTITIAL CIRCUMFERENTIAL MARGIN.
G. OMENTUM WITH MINUTE FOCUS OF METASTATIC SIGNET RING CELL CARCINOMA.
H. AJCC 7TH EDITION PATHOLOGIC TUMOR STAGE: pT3 N3 M1.

PART 8: ESOPHAGUS AND SMALL BOWEL, ANASTOMOTIC RING, ESOPHAGOGASTRECTOMY –
ESOPHAGEAL AND SMALL BOWEL SEGMENTS, NEGATIVE FOR CARCINOMA.

PART 9: SMALL BOWEL, SEGMENTAL RESECTION –
SMALL BOWEL WITH FOCAL ACUTE SEROSITIS, NEGATIVE FOR METASTATIC CARCINOMA.

COMMENT:

Although the carcinoma measures 3.5 cm grossly it extends from the esophageal proximal margin to the distal margin of part 7 (esophagogastrectomy), which is a length of approximately 20 cm. An immunohistochemical stain for AE1/3 is performed on block 8 (anastomotic rings), which is negative for carcinoma. All controls reacted appropriately.

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY ESOPHAGEAL TUMORS****----- MACROSCOPIC -----**

SPECIMEN TYPE: Esophagogastrectomy
TUMOR SITE: Tumor midpoint in proximal stomach or cardia (within 5cm of EGJ) AND tumor involves esophagogastric junction
TUMOR SIZE: Greatest dimension: 3.5 cm
Additional dimensions: 3.0 cm

----- MICROSCOPIC -----

HISTOLOGIC TYPE: Adenocarcinoma
HISTOLOGIC GRADE:
PATHOLOGIC STAGING (pTNM)
pT3
pN3
Number of lymph nodes examined: 20
Number of lymph nodes involved: 23
pM1

PRIOR TREATMENT: Specify site(s): Iliac lymph nodes
Treatment history not known
MARGINS
Proximal margin uninvolved by invasive carcinoma
Distal margin uninvolved by invasive carcinoma
Circumferential (adventitial) margin involved by invasive carcinoma
ANGIOLYMPHATIC INVASION: Present

ADDITIONAL PATHOLOGIC FINDINGS: Other: Linitus plastica type growth

PATIENT HISTORY:

PRE-OP DIAGNOSIS: Esophageal cancer

POST-OP DIAGNOSIS:

PROCEDURE: Esophagectomy

Source: NCI Genomic Data Commons file d3b37e6e-dac2-4fdc-ac28-626ebf546131 (TCGA-IN-7808.C5E11794-6234-4A87-8B4D-53C60BA59F08.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).